Somatic mutation profile of tumor specimen MP2PRT-PARVFU-TMP1-A (aliquot MP2PRT-PARVFU-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARVFU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,847 days).
Specimen MP2PRT-PARVFU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6f1af1a-5ca9-4af1-be6b-93d9e5d94464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVFU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVFU-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a3e106f-83bb-46b3-9992-52a0bf36f4b5

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY1 | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 334/706 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs748614348, COSV52030450; called by muse, mutect2, varscan2
- E4F1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 173/408 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs776338481, COSV100065575; called by muse, mutect2, varscan2
- SERPINB2 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as rs560133768; called by muse, mutect2, varscan2
- AHNAK2 | c.7453del p.I2485Ffs*65 | Frame Shift Del (DEL) | VAF 58/462 reads (13%) | called by mutect2, pindel, varscan2
- CPS1 | c.484T>A p.Y162N | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- SLC1A7 | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 79/411 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRPM6 | c.5076A>T p.G1692= | Silent (SNP) | VAF 17/208 reads (8%) | called by muse, mutect2
- USH2A | c.15444C>T p.L5148= | Silent (SNP) | VAF 147/334 reads (44%) | catalogued as COSV56367649; called by muse, mutect2, varscan2
